Somatic mutation profile of tumor specimen TCGA-81-5910-01A (aliquot TCGA-81-5910-01A-11D-1696-08) from TCGA case TCGA-81-5910, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 64.5 years (23,567 days).
Specimen TCGA-81-5910-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9e8dd1b-4515-4097-b354-6715711c91ca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-81-5910-10A (Blood Derived Normal), aliquot TCGA-81-5910-10A-01D-1696-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a3c600d0-a324-45de-bdba-02f441515da6

The open-access MAF lists 50 somatic variants for this specimen: 35 protein-altering or splice-affecting, 12 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 12, Frame Shift Ins 2, Intron 2, Splice Region 2, Splice Site 1, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 104/1047 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.882); catalogued as COSV51767495, COSV51850592; called by muse, mutect2, varscan2
- PTEN | c.509G>A p.S170N | Missense Mutation (SNP) | VAF 64/79 reads (81%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM110142, COSV64288690, COSV64296946; called by muse, mutect2, varscan2
- ACSM1 | c.1116G>A p.T372= | Splice Region (SNP) | VAF 14/47 reads (30%) | catalogued as rs765295558, COSV54633186; called by muse, mutect2, varscan2
- AFF3 | c.2269C>G p.L757V | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs56151323, COSV57839968, COSV57861157; called by muse, mutect2, varscan2
- ANAPC4 | c.1685+2T>C p.X562_splice | Splice Site (SNP) | VAF 16/44 reads (36%) | catalogued as COSV59543003; called by muse, varscan2
- ANO1 | c.1918G>A p.V640M | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.593); catalogued as rs370304912, COSV60281545; called by muse, mutect2, varscan2
- CARD6 | c.2026G>A p.A676T | Missense Mutation (SNP) | VAF 67/145 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.082); catalogued as COSV54564400; called by muse, mutect2, varscan2
- CELSR1 | c.4577G>A p.R1526Q | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs377640697; called by muse, mutect2
- CEP83 | c.1133G>A p.R378H | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs781589454, COSV100352674, COSV60406717; called by muse, mutect2, varscan2
- CRELD1 | c.121C>A p.P41T | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV55972392; called by muse, mutect2, varscan2
- FN1 | c.2815G>T p.V939L | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as COSV100118209; called by muse, mutect2
- FREM1 | c.1201A>T p.T401S | Missense Mutation (SNP) | VAF 33/44 reads (75%) | SIFT tolerated (0.08); PolyPhen benign (0.041); catalogued as COSV63087153; called by muse, mutect2, varscan2
- KDR | c.3868A>C p.S1290R | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV55758690; called by muse, mutect2, varscan2
- LRFN5 | c.952A>G p.I318V | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0.23); catalogued as rs1232356765, COSV53244542, COSV53265356; called by muse, mutect2, varscan2
- LRP2 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs780002886, COSV55542352; called by muse, mutect2, varscan2
- MPP4 | c.863A>C p.Q288P | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59629131; called by muse, mutect2, varscan2
- MTHFSD | c.217G>A p.V73I (on ENST00000360900 / NM_001159377.2; = p.V72I on NM_022764.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/205 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as rs369108681, COSV59805073; called by muse, mutect2, varscan2
- MYH9 | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 99/237 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.22); catalogued as rs767088377, COSV53382430; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLRP12 | c.2015C>T p.A672V | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as rs376751517, COSV60743958; called by muse, mutect2, varscan2
- OR13F1 | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 70/172 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as rs774810702, COSV58250823; called by muse, mutect2, varscan2
- OR2L2 | c.530dup p.C178Lfs*2 | Frame Shift Ins (INS) | VAF 62/202 reads (31%) | catalogued as rs1490247970; called by mutect2, pindel, varscan2
- OR6N1 | c.529G>A p.V177I | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772389600, COSV58647480; called by muse, mutect2, varscan2
- PRKCA | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52579025; called by muse, mutect2
- RALGDS | c.2510A>G p.N837S | Missense Mutation (SNP) | VAF 68/183 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.772); catalogued as rs771418767, COSV64425775; called by muse, mutect2, varscan2
- RELN | c.3872G>A p.R1291Q | Missense Mutation (SNP) | VAF 41/192 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.945); catalogued as rs774998117, COSV58987379, COSV59033177; called by muse, mutect2, varscan2
- RYR1 | c.7029C>T p.G2343= | Splice Region (SNP) | VAF 10/29 reads (34%) | catalogued as rs138617219; called by muse, mutect2, varscan2
- SCN9A | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202083986, COSV57599428; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCNN1B | c.1253G>A p.R418Q | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs201649568; called by muse, mutect2, varscan2
- STAB2 | c.4247G>T p.C1416F | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66334977; called by muse, mutect2, varscan2
- STAG2 | c.328C>T p.R110* | Nonsense Mutation (SNP) | VAF 43/47 reads (91%) | catalogued as COSV54351672; called by muse, mutect2, varscan2
- STK40 | c.473A>G p.N158S | Missense Mutation (SNP) | VAF 121/278 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.921); catalogued as rs1240128909, COSV63734759; called by muse, mutect2, varscan2
- STXBP5L | c.1821T>G p.I607M | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.757); catalogued as COSV56501740; called by muse, mutect2, varscan2
- TRBV3-1 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.343); catalogued as rs959033905; called by muse, mutect2, varscan2
- USH2A | c.2777G>A p.R926H | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.12); catalogued as rs146916397; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- CTPS1 | c.841dup p.M281Nfs*10 | Frame Shift Ins (INS) | VAF 19/53 reads (36%) | called by mutect2, pindel, varscan2
- FBXL13 | c.9G>A p.P3= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs760375206, COSV57535174; called by muse, mutect2
- IFI44L | c.498C>T p.D166= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as rs886532970, COSV60726830, COSV60728187; called by muse, mutect2, varscan2
- LAMA1 | c.8004C>T p.V2668= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as rs776351965, COSV67532714; called by muse, mutect2, varscan2
- MCM7 | c.1755C>T p.Y585= | Silent (SNP) | VAF 37/133 reads (28%) | catalogued as rs762734756, COSV57994137; called by muse, mutect2, varscan2
- NDN | c.627C>T p.A209= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as COSV59358550; called by muse, mutect2, varscan2
- NOBOX | c.429G>A p.P143= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as rs748148557, COSV56192840; called by muse, mutect2, varscan2
- PAX3 | c.1191C>T p.T397= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as COSV60586382; called by muse, mutect2
- PCID2 | c.141G>A p.E47= | Silent (SNP) | VAF 37/94 reads (39%) | catalogued as COSV55812977; called by muse, mutect2, varscan2
- PDCD2L | c.246C>T p.C82= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV55824724; called by muse, varscan2
- SETBP1 | c.2853C>T p.L951= | Silent (SNP) | VAF 33/66 reads (50%) | catalogued as COSV56313879; called by muse, mutect2, varscan2
- TTN | c.37968C>T p.G12656= (on ENST00000591111; = p.G5232= on NM_003319.4) | Silent (SNP) | VAF 35/61 reads (57%) | catalogued as rs550471556, COSV59905124; ClinVar: uncertain significance / likely benign / benign; called by muse, mutect2, varscan2
- ZNF536 | c.321C>T p.N107= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs144245375; called by muse, mutect2, varscan2
- AC092718.9 | chr16:81148170 G>A | 5'Flank (SNP) | VAF 6/26 reads (23%) | catalogued as rs764653770; called by muse, mutect2, varscan2
- DOCK8 | c.53+13C>A | Intron (SNP) | VAF 7/13 reads (54%) | catalogued as rs1056951278, COSV66687961, COSV66688259; called by muse, mutect2
- MYO3B | c.3734-4705G>A | Intron (SNP) | VAF 35/121 reads (29%) | catalogued as rs766982539, COSV58711259; called by muse, mutect2, varscan2
